Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A2N3, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A2N3-01B (Primary Tumor).

SPECIMEN TAKEN: C

FINAL DIAGNOSIS ----- Pathologist:
LEFT LOBE, THYROID (PARTIAL THYROIDECTOMY):

SPECIMEN TYPE:

Left lobectomy

1cD-0.3

carcinoma, papillary, follicular variant 8340/3

TUMOR SITE:

Left lobe

Site: thyroid, nos C73.4

fw
8/18/11

HISTOLOGIC TYPE:

Papillary carcinoma, follicular variant

TUMOR SIZE (LARGEST NODULE):

Greatest dimension: 4 cm

FOCALITY:

Unifocal

LYMPH NODES:

None submitted.

EXTENT OF INVASION (STAGING):

Primary Tumor

pT2: Tumor >2 cm but < or equal to 4 cm, limited to thyroid

REGIONAL LYMPH NODES:

pNx: Cannot be assessed

DISTANT METASTASIS:

pMx: Cannot be assessed

VENOUS/LYMPHATIC INVASION: Absent

ADDITIONAL PATHOLOGIC FINDINGS:

None identified

Source: NCI Genomic Data Commons file 4f23aaed-9bb8-4f86-a5f9-e7091692ce2d (TCGA-ET-A2N3.2C8DF5EC-3C30-4A19-AFDA-58A6FD94CFB8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).